Surgical pathology report (de-identified scan), TCGA case TCGA-B8-4151, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site UNC, specimen TCGA-B8-4151-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Surgical Pathology Report

Accession #:

Diagnosis:

Right kidney, nephrectomy

Histologic tumor type/subtype: renal cell carcinoma, clear cell type

Histologic grade (if applicable): 2 (of 4, classification)

Tumor size (greatest dimension): 6.7 cm diameter (gross)

Extent of tumor invasion:

Extra-capsular invasion: present, perihilar / renal sinus fat (A9)

Renal vein: tributary involved (A11), but not involving renal vein margin (A1)

Ureter: not identified

Venous (large vessel): see above

Lymphatic (small vessel): not identified

Depth of invasion: n/a

Adjacent organs: none received

Surgical margins:

Perirenal adipose tissue: not involved

Renal vein: not involved

Renal artery: not identified

Ureter: not identified

Adrenal gland: not received

Lymph nodes: not received

[page 2 of 3]
Other significant findings: none

AJCC Staging: pT3 pNx pMx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

The patient is a with a clinical diagnosis of a kidney mass in the right kidney. As per [REDACTED], abdominal CT shows a mass of the right kidney that extends from the medial to interpolar region and measures 7.3 x 5.6 cm. Smaller lesions are also noted in the lower pole but are too small to characterize.

Gross Description:

Received is one appropriately labeled container.

Specimen A is additionally labeled "right kidney".

Specimen fixation: formalin

Type of specimen: total nephrectomy, right side

Side of specimen: right

Size and weight of specimen: Weight 600 g; the specimen measures 16.0 x 9.5 x 6.5 cm overall; the kidney measures 12.5 x 5.6 x 6.0 cm.

Orientation: The specimen has been previously opened and the perirenal fat has been inked blue.

Presence/absence of adrenal gland: absent

Tumor description/site: The tumor is located in the lower pole of the kidney and measures 6.7 x 3.7 x 2.5 cm; there appears to be a thin capsule surrounding a portion of the tumor; the tumor itself is yellow to gold in color with focal areas of brown discoloration. No necrosis is evident.

Tumor size: 6.7 x 3.7 x 2.5 cm

Presence/absence of multicentricity: absent

[page 3 of 3]
Confinement/non-confinement to the kidney: confined

Extent of invasion:

Perirenal adipose tissue: does not grossly involve
Gerota' s fascia: not present
Renal vein: does not grossly involve
Ureter: does not grossly involve
Other organs: not applicable

Surgical margins:

Perirenal adipose tissue: negative; closest margin of resection is 0.5 cm
Renal vein: negative; 2.0 cm away
Renal artery: negative; 2.0 cm away
Ureter: negative; 2.0 cm away

Description of kidney away from tumor: The remainder of the kidney appears tan-brown in color with no evidence of other satellite lesions or masses; the average medullary region measures 1.2 cm and the average cortical region measures 0.6 cm.

Lymph nodes (hilar): non-identified

Other significant findings: no

Tissue submitted for special investigations: no

Digital photograph taken: no

Block Summary:

Blue = perirenal fat; (margin of resection)
A1 - vascular and ureteral margins
A2 - tumor in closest inked perinephric soft tissue
A3 - tumor and renal capsule
A4 - tumor with transition into normal parenchyma
A5-A6 - central tumor (two slices per cassette)
A7 - normal kidney, upper pole, one representative section
A8-A9 - tumor and adjacent urothelium
A10 - hilar fat, en face
A11 - additional section of tumor with urothelium

Source: NCI Genomic Data Commons file 04a82a00-b2df-4f8a-9f11-1eca0f7bd5d3 (TCGA-B8-4151.BA492F01-797C-4780-A461-44305B04A178.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).